Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4968, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4968-01A (Primary Tumor).

[page 1 of 3]
TCGA-BP-4968

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with renal mass, right side.

Specimens Submitted:

- 1: KIDNEY, RIGHT; RADICAL NEPHRECTOMY
- 2: BONE AND CARTILAGE, PORTION OF 11TH RIB; EXCISION:
- 3: SOFT TISSUE, PERINEPHRIC FAT:
- 4: LYMPH NODE, HILAR; EXCISION:

DIAGNOSIS:

1. KIDNEY, RIGHT; RADICAL NEPHRECTOMY:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.5 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Unremarkable

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor <= 7.0 cm in greatest dimension limited to the kidney

**2. BONE AND CARTILAGE, PORTION OF 11TH RIB; EXCISION::
BENIGN CHONDRO-OSSEOUS TISSUE AND SKELETAL MUSCLE**

[page 2 of 3]
3. SOFT TISSUE, PERINEPHRIC FAT::
BENIGN ADIPOSE TISSUE

4. LYMPH NODE, HILAR; EXCISION::

Lymph Nodes:

Not Involved

Number of nodes examined:3

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh for frozen diagnosis labeled "right kidney" and consists of a kidney with attached ureter, renal vessels and perinephric fat weighing 395 g in total. The kidney measures 10.5 x 6.4 x 5.5 cm. The attached ureter measures 8.0 cm in length and 0.3 cm in diameter. The attached renal vein measures 1.0 cm in length and 0.8 cm in diameter. The renal vessels and ureter margins are grossly unremarkable. An adrenal gland is not identified. The kidney is inked black and bivalved to reveal a yellow and hemorrhagic, circumscribed mass which appears to extend into the perinephric fat measuring 5.5 x 2.5 x 2.2 cm. Sections through the remainder of the kidney reveal a pink brown parenchyma, with a well-defined corticomedullary junction. The cortex measures 1.0 cm and the calyces appear normal. No lymph nodes are identified in the perinephric fat. Representative sections are submitted for TPS and for permanent sections.

Summary of sections:

FSC-frozen section control

UVM -- ureteral and vessel margins

T-- tumor

TSF -- tumor with sinus fat

TK -- tumor with adjacent kidney

RP -- renal pelvis representative sections

K -- representative sections kidney

2). The specimen is received in formalin labeled "portion of right 11th rib". It consists of a segment of bone with attached soft tissue measuring 4.8 x 1.3 x 1.1 cm. The specimen is grossly unremarkable. A representative section is submitted.

Summary sections:

B- bone

3). The specimen is received in formalin labeled "perinephric fat". It consists of yellow fat measuring 3.2 x 3.1 x 0.9 cm. Representative sections are submitted.

Summary sections:

ST-soft tissue

4). The specimen is received in formalin labeled "hilar lymph nodes". It consists of multiple fragments of pale and tan soft tissue with attached metallic and plastic clips measuring 2.1 x 1.7 x 0.8 cm in aggregate. The clips are removed, and the tissue is entirely submitted.

Summary sections:

LN-lymph nodes

[page 3 of 3]
Summary of Sections:

Part 1: KIDNEY, RIGHT; RADICAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
1	k	1
1	rp	1
4	t	4
1	tk	1
1	tsf	1
1	uvm	1

Part 2: BONE AND CARTILAGE, PORTION OF 11TH RIB; EXCISION:

Block	Sect. Site	PCs
1	b	1

Part 3: SOFT TISSUE, PERINEPHRIC FAT:

Block	Sect. Site	PCs
1	st	1

Part 4: LYMPH NODE, HILAR; EXCISION:

Block	Sect. Site	PCs
1	ln	1

Intraoperative Consultation:

The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM, FAVOR CLEAR CELL TYPE ON REPRESENTATIVE SECTION. [REDACTED]
PERMANENT DIAGNOSIS: SAME [REDACTED]

Source: NCI Genomic Data Commons file 989c9a22-e04c-41e1-8ced-163d09f3df7b (TCGA-BP-4968.A9535099-2FA1-421A-95BC-3AD5FBA840ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).